Gene-level copy-number profile of tumor specimen ALCH-B74K-TTP1-A from ALCHEMIST case ALCH-B74K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,032 days).
Specimen ALCH-B74K-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b06696d-4d56-41e7-b51d-c097199cfebe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B74K-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/8e02787f-8785-4211-a7fe-1be1fd5d1fa6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 217; copy number 1: 6,611; copy number 2: 50,076; copy number 3: 1,448; copy number 4: 18; copy number 5: 7; copy number 6: 9; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 217 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–522,928, 25 genes (within-gene range 0–1): OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene: AC114498.1.
- chr2:130,151,392–130,182,750, 1 gene (within-gene range 0–1): SMPD4.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,493,156, 3 genes (within-gene range 0–2): MIR601, MIR7150, AL445489.1.
- chr9:124,777,133–124,877,733, 4 genes: OLFML2A, WDR38, RPL35, ARPC5L.
- chr11:77,128,246–77,215,241, 1 gene: MYO7A.
- chr13:113,923,052–113,928,991, 1 gene (within-gene range 0–1): LINC00565.
- chr14:18,333,726–19,684,739, 66 genes (broad region; genes not listed).
- chr15:25,182,385–25,201,404, 11 genes (within-gene range 0–2): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17.
- chr15:25,208,083–25,225,284, 10 genes (within-gene range 0–2): SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:46,469,341–46,649,849, 8 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1.
- chr17:142,789–191,587, 2 genes (within-gene range 0–1): DOC2B, LINC02091.
- chr17:30,567,700–30,571,748, 1 gene: KRT17P3.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–1): AC127024.7, AC127024.3, AC127024.2.
- chr17:45,999,250–45,999,694, 1 gene (within-gene range 0–1): STH.
- chr19:5,782,960–5,791,225, 3 genes: PRR22, AC011499.1, DUS3L.
- chr19:24,146,701–27,646,483, 4 genes: AC073534.2, AC073534.1, ERVK-28, AC112702.1.
- chr20:37,903,111–37,945,350, 1 gene: VSTM2L.
- chr21:8,701,461–13,120,807, 46 genes: CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr22:17,787,649–18,024,561, 7 genes (within-gene range 0–1): MICAL3, AC016026.1, AC016026.2, MIR648, AC016027.3, AC016027.2, RHEBP3.
- chr22:18,150,170–18,177,397, 1 gene: USP18.
- chr22:18,400,407–18,530,573, 8 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:41,205,282–41,240,931, 3 genes (within-gene range 0–2): L3MBTL2, L3MBTL2-AS1, CHADL.
- chr22:41,252,992–41,253,050, 1 gene (within-gene range 0–1): MIR6889.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 6: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr5:710,355–850,986, 4 genes, copy number 5 (within-gene range 3–5): ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3.
- chr19:1,021,522–1,039,068, 3 genes, copy number 6: RNU6-2, CNN2, AC011558.1.
- chr19:1,065,923–1,106,791, 3 genes, copy number 5–6: ARHGAP45, POLR2E, GPX4.
- chr21:43,461,960–43,479,534, 2 genes, copy number 11: LINC00313, AP001048.1.
- chr22:18,623,339–18,625,289, 1 gene, copy number 5: SUSD2P2.

Autosomal genes at a single copy (total copy number 1): 6,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
